Somatic mutation profile of tumor specimen C3L-03589-03 (aliquot CPT0188710006) from CPTAC case C3L-03589, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,871 days).
Specimen C3L-03589-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 610c68da-e045-497b-b9df-8d97e99d2ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03589-71 (Blood Derived Normal), aliquot CPT0188770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd94d2e2-2a35-4bf8-9d56-31a0dd6034d9

The open-access MAF lists 995 somatic variants for this specimen: 647 protein-altering or splice-affecting, 216 silent, 132 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 454, Silent 216, Frame Shift Del 110, Intron 68, Frame Shift Ins 25, 3'UTR 21, RNA 21, Nonsense Mutation 20, Splice Site 17, Splice Region 12, 5'UTR 12, 5'Flank 5.

Variants (750 of 995; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPR1 | c.5455C>T p.R1819* (on ENST00000354582; = p.R1764* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 101/368 reads (27%) | catalogued as rs1249951465, COSV100232552, COSV57002930; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 114/383 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2079del p.K693Nfs*43 | Frame Shift Del (DEL) | VAF 153/513 reads (30%) | catalogued as rs267608083; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 456/618 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PXDN | c.2568dup p.C857Lfs*10 | Frame Shift Ins (INS) | VAF 69/206 reads (33%) | catalogued as rs558163499; ClinVar: pathogenic; called by mutect2, varscan2
- TOPORS | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as rs869312183, CM1211750; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3047G>A p.G1016D (on ENST00000326724 / NM_001080395.3; = p.G913D on NM_004920.2) | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs772308883, COSV58372157; called by muse, mutect2, varscan2
- ABCC2 | c.2556del p.G853Efs*7 | Frame Shift Del (DEL) | VAF 113/581 reads (19%) | catalogued as rs1393497113, COSV64984621, COSV64985681; called by mutect2, pindel, varscan2
- ABI3BP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV52530679, COSV99425310; called by muse, mutect2, varscan2
- ACP3 | c.968+3_968+6del p.X323_splice | Splice Site (DEL) | VAF 95/264 reads (36%) | catalogued as rs1250703113; called by mutect2, pindel, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs760140619; called by mutect2, varscan2
- AIG1 | c.134T>G p.I45S | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51631312; called by muse, varscan2
- ALDH1A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs778276187, COSV52789879; called by muse, mutect2, varscan2
- ALG13 | c.1853G>C p.S618T | Missense Mutation (SNP) | VAF 202/605 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs1194966893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.2837C>T p.S946L (on ENST00000458649 / NM_001367468.1; = p.S856L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs932975059, COSV54062015; called by muse, mutect2, varscan2
- ANKRD45 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 83/415 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as rs1227973549, COSV60961987; called by muse, mutect2, varscan2
- APBA1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1443545402, COSV99596589; called by muse, mutect2, varscan2
- APBB2 | c.1265G>A p.R422H (on ENST00000295974 / NM_001166050.2; = p.R423H on NM_004307.2) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1170607832; called by muse, mutect2
- ARHGAP39 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52768235; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 93/268 reads (35%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 84/264 reads (32%) | catalogued as rs753865255; called by mutect2, varscan2
- ASIC5 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1325989631, COSV101539722; called by muse, mutect2, varscan2
- ASTN2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 113/296 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.964); catalogued as rs761710154, COSV57807854; called by muse, mutect2, varscan2
- ATM | c.3856T>G p.C1286G | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as CD982454; called by muse, mutect2, varscan2
- ATP10A | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs763619413, COSV63520561; called by muse, mutect2, varscan2
- ATP1A4 | c.276del p.T93Pfs*48 | Frame Shift Del (DEL) | VAF 149/642 reads (23%) | catalogued as rs760258351; called by mutect2, varscan2
- BAG6 | c.344dup p.G116Wfs*11 | Frame Shift Ins (INS) | VAF 56/284 reads (20%) | catalogued as rs761315497; called by mutect2, varscan2
- BAHCC1 | c.2502dup p.H835Afs*239 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as rs1555653772; called by mutect2, varscan2
- BAHCC1 | c.4813C>T p.R1605C | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs782635602, COSV57023142; called by muse, mutect2, varscan2
- BCL11B | c.1517C>T p.A506V (on ENST00000357195 / NM_001282237.2; = p.A435V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/421 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV61736336; called by muse, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | catalogued as rs749168305; called by mutect2, varscan2
- BHLHA9 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1398104020; called by mutect2, varscan2
- BIN2 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 135/466 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs1365076828; called by muse, mutect2, varscan2
- BRPF3 | c.3598G>A p.V1200I | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1232553385, COSV60207873; called by muse, mutect2, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs780875081; called by mutect2, varscan2
- C1QTNF8 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs561284506; called by muse, mutect2
- C1orf115 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1246633378; called by muse, mutect2, varscan2
- C8orf33 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1480436514; called by muse, mutect2, varscan2
- C9 | c.476+1G>T p.X159_splice | Splice Site (SNP) | VAF 132/457 reads (29%) | catalogued as COSV99662609; called by muse, mutect2, varscan2
- CAD | c.6023C>T p.A2008V | Missense Mutation (SNP) | VAF 177/553 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1393122122; called by muse, mutect2, varscan2
- CALHM3 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs373768643; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CARHSP1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs1282333000, COSV60683687; called by muse, mutect2, varscan2
- CCDC107 | c.656_658del p.E219_I220delinsV | In Frame Del (DEL) | VAF 96/361 reads (27%) | catalogued as rs747714583; called by mutect2, pindel, varscan2
- CCR7 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as rs147082234; called by muse, mutect2, varscan2
- CDHR2 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs773697758, COSV56144718; called by muse, mutect2, varscan2
- CELSR3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1334467053; called by muse, mutect2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFH | c.3077G>T p.G1026V | Missense Mutation (SNP) | VAF 154/785 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66407861; called by muse, mutect2, varscan2
- CHD3 | c.720dup p.A241Rfs*9 | Frame Shift Ins (INS) | VAF 52/211 reads (25%) | catalogued as rs745968236; called by mutect2, pindel
- CHD4 | c.4018C>T p.R1340* (on ENST00000357008 / NM_001363606.2; = p.R1353* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 47/151 reads (31%) | catalogued as COSV100537977; called by muse, mutect2, varscan2
- CLSTN1 | c.2066C>T p.T689M (on ENST00000377298 / NM_001009566.3; = p.T679M on NM_014944.4) | Missense Mutation (SNP) | VAF 97/333 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs777858203, COSV63649044; called by muse, mutect2, varscan2
- CMYA5 | c.9500G>A p.R3167Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1368355148; called by muse, mutect2, varscan2
- CNBD2 | c.1511T>G p.L504R (on ENST00000373973 / NM_001365709.1; = p.L500R on NM_080834.4) | Missense Mutation (SNP) | VAF 171/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100839076; called by muse, mutect2, varscan2
- COCH | c.1331G>A p.G444E (on ENST00000216361 / NM_001347720.1; = p.G379E on NM_004086.3) | Missense Mutation (SNP) | VAF 189/532 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167190599; called by muse, mutect2, varscan2
- COL18A1 | c.3241G>A p.G1081S (on ENST00000359759 / NM_130444.3; = p.G846S on NM_030582.4) | Missense Mutation (SNP) | VAF 109/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs529458355; called by muse, mutect2, varscan2
- CREBBP | c.6281C>T p.P2094L | Missense Mutation (SNP) | VAF 346/1089 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52114696; called by muse, mutect2, varscan2
- CSDE1 | c.926C>T p.T309I (on ENST00000358528 / NM_001007553.3; = p.T278I on NM_007158.6) | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54762780; called by muse, mutect2, varscan2
- CSMD3 | c.3583G>A p.G1195R (on ENST00000297405 / NM_001363185.1; = p.G1091R on NM_052900.3) | Missense Mutation (SNP) | VAF 163/524 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52231204; called by muse, mutect2, varscan2
- CST7 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.019); catalogued as rs897220469; called by muse, mutect2, varscan2
- CYP2B6 | c.103C>A p.R35S | Missense Mutation (SNP) | VAF 138/399 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs755215477, COSV60698140, COSV60699274; called by muse, mutect2, varscan2
- DAPK2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764655277, COSV56043853; called by muse, mutect2, varscan2
- DCP1B | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs768820815, COSV54973335; called by muse, mutect2, varscan2
- DECR2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs765990942, COSV54796544; called by muse, mutect2, varscan2
- DENND4C | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV66822088; called by muse, mutect2, varscan2
- DGKH | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 58/233 reads (25%) | catalogued as rs1282628642; called by muse, mutect2, varscan2
- DMBT1 | c.5740T>C p.Y1914H (on ENST00000338354 / NM_001377530.1; = p.Y1157H on NM_004406.3) | Missense Mutation (SNP) | VAF 111/472 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.983); catalogued as rs1565959717; called by muse, mutect2, varscan2
- DNHD1 | c.1491G>T p.R497S | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV54444358; called by muse, mutect2, varscan2
- DOCK4 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV70326315; called by muse, mutect2, varscan2
- DOCK6 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs751572807, COSV53914041; called by muse, mutect2, varscan2
- DPP9 | c.1148del p.P383Rfs*15 (on ENST00000598800; = p.P412Rfs*15 on NM_139159.5) | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | catalogued as rs747759328, COSV53593143; called by mutect2, pindel, varscan2
- DRD4 | c.908dup p.D304Gfs*146 | Frame Shift Ins (INS) | VAF 26/112 reads (23%) | catalogued as rs1203716308; called by pindel, varscan2
- DSC2 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 74/247 reads (30%) | catalogued as rs794728075, CM1314712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG3 | c.1255G>C p.A419P | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1429193825, COSV99934607; called by muse, mutect2, varscan2
- DUSP22 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 74/753 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV60532493; called by muse, mutect2, varscan2
- EEF2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs772293215; called by muse, mutect2, varscan2
- EFS | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs544344826; called by muse, mutect2
- EFTUD2 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV68183629; called by muse, mutect2, varscan2
- EGR4 | c.1390C>T p.R464C (on ENST00000545030; = p.R361C on NM_001965.4) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101474286; called by muse, mutect2, varscan2
- EHBP1L1 | c.815del p.G272Afs*3 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as COSV100499786, COSV58574308; called by mutect2, pindel, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF3E | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99622860; called by muse, mutect2, varscan2
- ENOSF1 | c.926T>C p.V309A (on ENST00000340116 / NM_001354066.2; = p.V261A on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51896234; called by muse, mutect2, varscan2
- EP300 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs149456776, COSV54330438; ClinVar: not provided; called by muse, varscan2
- EPHA3 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs577908847; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 52/133 reads (39%) | catalogued as rs768793415; called by mutect2, varscan2
- ESR1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 174/825 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs371610514, COSV52798510; called by muse, mutect2, varscan2
- EVC | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 212/581 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759245991, COSV99382233; called by muse, mutect2, varscan2
- FAM214A | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99958011; called by muse, mutect2, varscan2
- FAM71C | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146401531; called by muse, mutect2, varscan2
- FAM83H | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 286/881 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV62028785; called by muse, mutect2, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 47/149 reads (32%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO24 | c.265C>T p.R89C (on ENST00000241071 / NM_033506.3; = p.R127C on NM_012172.5) | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs563719782, COSV53823656; called by muse, mutect2, varscan2
- FBXO44 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 175/596 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52356204; called by muse, mutect2, varscan2
- FBXO7 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs762037477, COSV56677997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/179 reads (29%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP9 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV54227443; called by muse, mutect2, varscan2
- FRMPD2 | c.3161C>T p.T1054M | Missense Mutation (SNP) | VAF 95/598 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs782265552, COSV100564202; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 83/218 reads (38%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSIP2 | c.1139del p.N380Tfs*16 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs1559014390; called by mutect2, varscan2
- FTCD | c.367+2T>C p.X123_splice | Splice Site (SNP) | VAF 37/115 reads (32%) | catalogued as rs1484053262; called by muse, mutect2, varscan2
- FUT4 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as rs773297155; called by muse, mutect2, varscan2
- FUZ | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs200311325, COSV58241042; called by muse, varscan2
- G2E3 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1413295887, COSV52843012, COSV52843128; called by muse, mutect2, varscan2
- GADL1 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 141/407 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV56977185; called by muse, mutect2, varscan2
- GATA4 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 291/848 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs116430078, COSV58733683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFI1B | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs560461496; called by muse, mutect2, varscan2
- GLIS3 | c.1517del p.K506Sfs*145 | Frame Shift Del (DEL) | VAF 129/459 reads (28%) | catalogued as COSV100173970; called by mutect2, pindel, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GPS2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100223185; called by muse, mutect2, varscan2
- GRAMD2A | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59034157; called by muse, mutect2
- GRIN2D | c.2797G>A p.V933M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.055); catalogued as rs1177940200; called by mutect2, varscan2
- GRM4 | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs367884671; called by muse, mutect2
- GTF3C4 | c.1685A>G p.E562G | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV64645321; called by muse, mutect2, varscan2
- HDAC1 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1347515093; called by muse, mutect2
- HDX | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs1345649799, COSV99946802; called by muse, mutect2, varscan2
- HEPH | c.3255dup p.R1086Qfs*4 (on ENST00000343002; = p.R819Qfs*4 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 76/254 reads (30%) | catalogued as rs750060613; called by mutect2, pindel, varscan2
- HERC1 | c.10320del p.G3441Vfs*61 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | catalogued as rs142218127; called by mutect2, pindel, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HIPK3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV57561750; called by muse, mutect2, varscan2
- HMCN1 | c.16658G>A p.R5553Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148530862; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 43/118 reads (36%) | catalogued as rs761272507; called by mutect2, varscan2
- HSD17B6 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs764447697; called by muse, mutect2
- IGHE | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 97/662 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781794644; called by muse, mutect2, varscan2
- IGKV1-6 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 64/696 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as rs751472625; called by muse, mutect2
- IGSF10 | c.7532G>C p.S2511T | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as rs912869155; called by muse, mutect2, varscan2
- IMPDH2 | c.541_542del p.K181Efs*18 | Frame Shift Del (DEL) | VAF 73/325 reads (22%) | catalogued as rs747572592; called by mutect2, pindel, varscan2
- INPPL1 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs138596491; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IQSEC1 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs951875351; called by muse, mutect2
- IRF2BPL | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as rs750852964; called by muse, mutect2, varscan2
- ITIH6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 97/361 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs1018591321; called by muse, mutect2, varscan2
- ITPKB | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 96/473 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99685372; called by muse, mutect2, varscan2
- JAK2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs368927897, CM1111733, COSV67590089, COSV67606947; called by muse, mutect2, varscan2
- KCNC3 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 154/436 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs763961794; called by muse, mutect2, varscan2
- KCNG2 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766517685, COSV100302146, COSV60270833; called by muse, mutect2, varscan2
- KCNV2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 232/694 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781606821; called by muse, mutect2, varscan2
- KIF13A | c.4346A>G p.H1449R | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.119); catalogued as rs1467194992; called by muse, mutect2, varscan2
- KPRP | c.619del p.Q207Sfs*4 | Frame Shift Del (DEL) | VAF 136/911 reads (15%) | catalogued as rs1160391112; called by mutect2, pindel, varscan2
- KRIT1 | c.716A>G p.Q239R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.885); catalogued as rs1405947289; called by muse, mutect2, varscan2
- KRT3 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 170/528 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777747344; called by muse, mutect2, varscan2
- KRT73 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs758072157; called by muse, mutect2, varscan2
- LDLRAD4 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs371089156; called by muse, mutect2, varscan2
- LIPC | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 218/656 reads (33%) | catalogued as rs1408986383, COSV54422061; called by muse, mutect2, varscan2
- LIPJ | c.931del p.S311Vfs*32 | Frame Shift Del (DEL) | VAF 38/189 reads (20%) | catalogued as COSV64245373; called by mutect2, pindel, varscan2
- LRFN4 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV58920907; called by muse, mutect2, varscan2
- LRP2 | c.9664A>G p.I3222V | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.968); catalogued as rs528833441; called by muse, mutect2, varscan2
- LRRC43 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs368234675; called by muse, mutect2, varscan2
- LRRC6 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | catalogued as rs150975285; called by muse, mutect2, varscan2
- LTO1 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 37/460 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs985594243, COSV54163599; called by muse, mutect2
- MAPK4 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1417419801; called by muse, mutect2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 57/234 reads (24%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MFSD3 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.376); catalogued as rs138616461, COSV56741817; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs762448666; called by mutect2, pindel
- MOB3A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1316038193, COSV63865981; called by muse, mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 34/143 reads (24%) | catalogued as rs753079987; called by mutect2, varscan2
- MPRIP | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 131/402 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1175028801; called by muse, mutect2, varscan2
- MR1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 92/543 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748694184; called by muse, mutect2, varscan2
- MRTFB | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1409853586, COSV100371971; called by muse, mutect2, varscan2
- MTF2 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs770893619; called by muse, mutect2, varscan2
- MUC16 | c.8257G>A p.A2753T | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67469278; called by muse, mutect2, varscan2
- MUC2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.01); catalogued as rs377318400; called by muse, mutect2, varscan2
- MYBBP1A | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 164/476 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs749510484, COSV54593739, COSV99626311; called by muse, varscan2
- MYOG | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 121/667 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376105946; called by muse, mutect2, varscan2
- NAF1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | catalogued as rs1397750674; called by muse, mutect2, varscan2
- NANOS1 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100403895; called by muse, mutect2, varscan2
- NAT16 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55865466; called by muse, mutect2, varscan2
- NCOR2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1356048366, COSV100656936; called by muse, mutect2, varscan2
- NFE2L3 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV50228018, COSV50229748; called by muse, mutect2, varscan2
- NHLRC2 | c.1815del p.V606* | Frame Shift Del (DEL) | VAF 27/162 reads (17%) | catalogued as COSV65174999; called by mutect2, pindel
- NKAP | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57629856; called by muse, mutect2, varscan2
- NOP14 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as rs1483693526; called by muse, mutect2, varscan2
- NOTCH1 | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 163/530 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as rs763098618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 155/696 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866171506, COSV100903833; called by muse, mutect2, varscan2
- NPY1R | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs113167456; called by muse, mutect2, varscan2
- NSMAF | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs767516323, COSV50689663; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 182/872 reads (21%) | catalogued as rs760869296; called by mutect2, varscan2
- OLFML2B | c.868G>C p.A290P | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99668481; called by muse, mutect2, varscan2
- OR10H5 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs750292924, COSV58278783; called by muse, mutect2, varscan2
- OR4L1 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV59849016; called by muse, mutect2, varscan2
- PADI1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038313993; called by muse, mutect2, varscan2
- PARP1 | c.1427A>G p.H476R | Missense Mutation (SNP) | VAF 129/726 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1303502360; called by muse, mutect2, varscan2
- PCDHAC1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411970319; called by muse, mutect2
- PCDHB5 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 256/888 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.113); catalogued as rs1554276173, COSV50679282; called by muse, mutect2, varscan2
- PCDHB6 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 275/949 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as rs782345798, COSV50689632; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 76/232 reads (33%) | catalogued as rs772305388; called by mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 64/205 reads (31%) | catalogued as COSV61618667; called by mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as rs759495724; called by mutect2, varscan2
- PHF19 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs956008523, COSV100876257; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3CB | c.2884T>A p.Y962N | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV56687617; called by muse, mutect2, varscan2
- PJA1 | c.1714G>A p.E572K (on ENST00000361478 / NM_145119.4; = p.E384K on NM_022368.5) | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1289454442; called by muse, mutect2, varscan2
- PNMA8B | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100885479; called by muse, mutect2, varscan2
- POLD1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1004124075, COSV70957316; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE2 | c.582A>T p.K194N | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs756610389, COSV53559987; called by muse, mutect2, varscan2
- POM121 | c.3749A>G p.*1250Wext*? (on ENST00000434423; = p.*985Wext*21 on NM_172020.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as COSV57516482; called by muse, mutect2, varscan2
- POMGNT1 | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 184/572 reads (32%) | PolyPhen benign (0.381); catalogued as rs1027415099; called by muse, mutect2, varscan2
- PPARG | c.1270+1G>A p.X424_splice (on ENST00000287820 / NM_015869.5; = p.X394_splice on NM_005037.7) | Splice Site (SNP) | VAF 68/216 reads (31%) | catalogued as COSV55140672; called by muse, mutect2, varscan2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as rs1056475720, COSV52881818; called by mutect2, pindel, varscan2
- PPP2R5D | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 143/597 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs779890347; called by muse, mutect2, varscan2
- PROKR1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 132/419 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV58139369; called by muse, mutect2, varscan2
- PRXL2A | c.218del p.N73Mfs*4 | Frame Shift Del (DEL) | VAF 68/316 reads (22%) | catalogued as COSV64690809; called by mutect2, varscan2
- PRXL2B | c.360G>A p.E120= (on ENST00000444521; = p.E90= on NM_152371.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 64/199 reads (32%) | catalogued as COSV56518275; called by muse, mutect2, varscan2
- PSAP | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 235/1086 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs774088864; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as rs1234606471; called by mutect2, pindel, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | catalogued as rs767679528; called by mutect2, varscan2
- RAE1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs753152734, COSV100982396; called by muse, mutect2, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 80/250 reads (32%) | catalogued as COSV99173620; called by mutect2, varscan2
- RAP1GAP | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs777201880, COSV99266249; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs773370779, COSV99532335; called by mutect2, pindel
- RBM33 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1332848716; called by muse, mutect2, varscan2
- RDX | c.1412dup p.P472Sfs*16 | Frame Shift Ins (INS) | VAF 79/287 reads (28%) | catalogued as rs780998172; called by mutect2, varscan2
- RHOBTB2 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs571326568; called by muse, mutect2, varscan2
- RNF123 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 97/285 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1305120007; called by muse, mutect2, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 48/183 reads (26%) | catalogued as COSV59688684; called by mutect2, pindel, varscan2
- RNF41 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100560180; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 105/347 reads (30%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPEPL1 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs193086300; called by muse, mutect2, varscan2
- RREB1 | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 84/425 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1236263326; called by muse, mutect2, varscan2
- RTRAF | c.531+5G>A | Splice Region (SNP) | VAF 30/101 reads (30%) | catalogued as rs762723183; called by muse, mutect2, varscan2
- RTTN | c.5026G>A p.A1676T | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.726); catalogued as rs981411269, COSV55347419; called by muse, mutect2, varscan2
- RUVBL1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59475753; called by muse, mutect2, varscan2
- SBNO2 | c.3752G>A p.C1251Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs544160705; called by muse, mutect2, varscan2
- SBNO2 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.263); catalogued as rs1359127254; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 88/229 reads (38%) | catalogued as rs757259031; called by mutect2, varscan2
- SCN1A | c.4265A>G p.Y1422C (on ENST00000303395 / NM_001202435.3; = p.Y1411C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917913, CM067012; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SDHA | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 225/619 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.165); catalogued as rs748683825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16A | c.6247_6248del p.S2083Tfs*20 | Frame Shift Del (DEL) | VAF 84/380 reads (22%) | catalogued as rs754091628; called by pindel, varscan2
- SFI1 | c.3530C>T p.A1177V (on ENST00000400288 / NM_001007467.3; = p.A1146V on NM_014775.4) | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs371893888; called by muse, mutect2, varscan2
- SGMS1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 122/529 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as rs948939561; called by muse, mutect2, varscan2
- SHANK2 | c.4736del p.P1579Rfs*49 | Frame Shift Del (DEL) | VAF 141/455 reads (31%) | catalogued as COSV53593252, COSV53603178; called by mutect2, varscan2
- SHROOM3 | c.5590G>A p.G1864S | Missense Mutation (SNP) | VAF 30/453 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.071); catalogued as rs186699969; called by muse, mutect2
- SIRPB2 | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs781677493; called by muse, mutect2, varscan2
- SIX6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1237413105, COSV59803403; called by muse, mutect2, varscan2
- SLC12A5 | c.2364del p.L789Cfs*38 (on ENST00000454036 / NM_001134771.2; = p.L766Cfs*38 on NM_020708.5) | Frame Shift Del (DEL) | VAF 72/215 reads (33%) | catalogued as rs1568866957; called by mutect2, pindel, varscan2
- SLC12A6 | c.3227C>T p.P1076L (on ENST00000354181 / NM_001365088.1; = p.P1025L on NM_005135.2) | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV51626427; called by muse, mutect2, varscan2
- SLC13A1 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs139339169; called by muse, mutect2
- SLC1A7 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs527517279; called by muse, mutect2, varscan2
- SLC24A5 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 118/433 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1312635224, COSV58316551; called by muse, mutect2, varscan2
- SLC25A30 | c.39del p.L14Wfs*15 | Frame Shift Del (DEL) | VAF 130/477 reads (27%) | catalogued as rs1208630857; called by mutect2, pindel, varscan2
- SLC4A3 | c.2652dup p.S885Qfs*83 | Frame Shift Ins (INS) | VAF 77/245 reads (31%) | catalogued as rs760972612; called by mutect2, varscan2
- SMUG1 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1248473191; called by muse, mutect2, varscan2
- SOD3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.022); catalogued as rs1266293499; called by muse, mutect2, varscan2
- SPATA31E1 | c.2818G>A p.A940T | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs775489978; called by muse, mutect2, varscan2
- SPEG | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1202434599; called by muse, mutect2, varscan2
- STING1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767228149, COSV58172536; called by muse, mutect2, varscan2
- STK11 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs746564972, COSV100479778; called by muse, mutect2, varscan2
- SUFU | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 182/772 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055194219; called by muse, mutect2, varscan2
- SVEP1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 198/608 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1392768047; called by muse, mutect2, varscan2
- SYNE1 | c.24605G>A p.R8202H (on ENST00000367255 / NM_182961.4; = p.R8131H on NM_033071.3) | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376102438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAB2 | c.1379C>T p.T460M | Missense Mutation (SNP) | VAF 138/559 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53853408; called by muse, mutect2, varscan2
- TAF6 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.01); catalogued as rs769557221; called by muse, mutect2, varscan2
- TAFA5 | c.229G>A p.G77S (on ENST00000402357 / NM_001082967.3; = p.G70S on NM_015381.7) | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055283390; called by muse, mutect2, varscan2
- TASOR2 | c.2689del p.T897Lfs*24 | Frame Shift Del (DEL) | VAF 125/585 reads (21%) | catalogued as rs1564335199; called by mutect2, pindel, varscan2
- TBC1D26 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1392549850, COSV101343596; called by muse, mutect2, varscan2
- TBL3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.197); catalogued as rs376312704; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 122/491 reads (25%) | catalogued as rs751224053; called by mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 118/374 reads (32%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | catalogued as rs746975641; called by mutect2, varscan2
- TJP2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as rs866010571, COSV55268376; called by muse, mutect2, varscan2
- TNFRSF1B | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1396127181; called by muse, mutect2, varscan2
- TNK2 | c.2717C>T p.T906M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.974); catalogued as rs755551695; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 38/150 reads (25%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TRIM11 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 125/754 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs746984282; called by muse, mutect2, varscan2
- TSSK6 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs1221692980; called by muse, mutect2, varscan2
- TTYH2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs1193625448; called by muse, mutect2
- UBN1 | c.2872del p.M958Cfs*7 | Frame Shift Del (DEL) | VAF 81/302 reads (27%) | catalogued as COSV99277799; called by mutect2, pindel, varscan2
- UBP1 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1351335682, COSV104369382; called by muse, mutect2, varscan2
- UGT2A1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99684930; called by muse, mutect2, varscan2
- UNC119B | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs750818826; called by muse, mutect2, varscan2
- USP13 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 111/380 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs530238022, COSV55865061, COSV55865634; called by muse, mutect2, varscan2
- USP21 | c.485del p.G162Afs*24 | Frame Shift Del (DEL) | VAF 104/561 reads (19%) | catalogued as COSV57089264, COSV57089431; called by mutect2, pindel, varscan2
- UTS2R | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1362270490, COSV100493433; called by muse, mutect2, varscan2
- VCP | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 181/509 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs752765916; called by muse, mutect2, varscan2
- VPS13D | c.12107T>C p.V4036A | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.774); catalogued as rs760996351; called by muse, mutect2, varscan2
- VPS33B | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 159/484 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs1018892338; called by muse, mutect2, varscan2
- VTN | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782820530, COSV56875240; called by muse, mutect2, varscan2
- VWA5B1 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1032767611, COSV57060692; called by muse, mutect2, varscan2
- WDR41 | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1252559183, COSV56997541; called by muse, mutect2, varscan2
- WDR81 | c.4919G>A p.R1640H (on ENST00000409644 / NM_001163809.2; = p.R589H on NM_152348.4) | Missense Mutation (SNP) | VAF 151/407 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs199654669, COSV58483314; called by muse, mutect2, varscan2
- WDR97 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 147/490 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs868307204; called by muse, mutect2, varscan2
- WNT4 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 108/322 reads (34%) | catalogued as COSV51602938; called by muse, mutect2, varscan2
- WWC2 | c.3055C>T p.R1019W | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67857663; called by muse, mutect2, varscan2
- ZC3H12A | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as rs765523307; called by muse, mutect2, varscan2
- ZC3H13 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.136); catalogued as rs1566366260, COSV54463388; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 44/146 reads (30%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFHX4 | c.6162_6165del p.P2056Hfs*26 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | catalogued as rs1554575033; called by mutect2, pindel, varscan2
- ZNF462 | c.4610G>A p.R1537Q | Missense Mutation (SNP) | VAF 178/470 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759410228, COSV52934985; called by muse, mutect2, varscan2
- ZNF541 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54543908; called by muse, mutect2, varscan2
- ZNF75D | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV66133528; called by muse, mutect2, varscan2
- ABCA5 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA7 | c.3776T>C p.I1259T | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ABCC8 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABHD2 | c.458dup p.N153Kfs*18 | Frame Shift Ins (INS) | VAF 48/196 reads (24%) | called by mutect2, pindel, varscan2
- AC011005.1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.328); called by muse, mutect2
- AC011462.1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 200/619 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACBD5 | c.273G>T p.W91C (on ENST00000375888 / NM_001352568.1; = p.W93C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/516 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP2 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACTR8 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ADCY10 | c.3869A>G p.E1290G | Missense Mutation (SNP) | VAF 48/1450 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- ADCY7 | c.1596-2A>G p.X532_splice | Splice Site (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- ADGRD2 | c.2213G>A p.S738N | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ADGRV1 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 17/402 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- AGO2 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AKAP9 | c.4186G>A p.A1396T | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALKBH8 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ALMS1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALPK2 | c.3794G>C p.G1265A | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANGPTL7 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 169/483 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ANK3 | c.76dup p.R26Kfs*15 | Frame Shift Ins (INS) | VAF 102/476 reads (21%) | called by mutect2, varscan2
- ANKRD28 | c.1898T>A p.L633* | Nonsense Mutation (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- ANO7 | c.1971G>A p.M657I (on ENST00000274979; = p.M603I on NM_001370694.2) | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- AP2A1 | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- APH1A | c.167T>C p.L56S | Missense Mutation (SNP) | VAF 76/420 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARAP3 | c.4409del p.P1470Lfs*12 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | called by mutect2, pindel, varscan2
- ARID1A | c.701dup p.R235Efs*165 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- ARID1A | c.3971A>G p.Y1324C | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARID1A | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARID4B | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ARNT | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ASPM | c.5615del p.L1872* | Frame Shift Del (DEL) | VAF 86/477 reads (18%) | called by mutect2, pindel, varscan2
- ATP5MD | c.154del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 75/332 reads (23%) | called by mutect2, pindel, varscan2
- ATRX | c.1618A>G p.S540G | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS10 | c.461del p.L154Cfs*17 | Frame Shift Del (DEL) | VAF 102/319 reads (32%) | called by mutect2, pindel, varscan2
- BCAR1 | c.813del p.M272Wfs*41 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.6965A>G p.E2322G | Missense Mutation (SNP) | VAF 119/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTN2A2 | c.881del p.K294Rfs*56 | Frame Shift Del (DEL) | VAF 98/468 reads (21%) | called by mutect2, pindel, varscan2
- C16orf70 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C3orf84 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 111/418 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- C5orf47 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMSAP3 | c.2502del p.E835Rfs*154 | Frame Shift Del (DEL) | VAF 106/343 reads (31%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASP7 | c.111-2A>G p.X37_splice | Splice Site (SNP) | VAF 32/185 reads (17%) | called by muse, mutect2, varscan2
- CASZ1 | c.1500+2T>C p.X500_splice | Splice Site (SNP) | VAF 70/204 reads (34%) | called by muse, mutect2, varscan2
- CCDC50 | c.1061T>A p.I354N (on ENST00000392455 / NM_178335.3; = p.I178N on NM_174908.4) | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT8 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCZ1 | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CD46 | c.1027+6T>C | Splice Region (SNP) | VAF 69/506 reads (14%) | called by muse, mutect2, varscan2
- CD55 | c.1060+7T>C | Splice Region (SNP) | VAF 38/197 reads (19%) | called by muse, mutect2, varscan2
- CDC23 | c.386dup p.K130Efs*4 | Frame Shift Ins (INS) | VAF 48/134 reads (36%) | called by mutect2, varscan2
- CDK5R1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDK5RAP1 | c.217T>C p.S73P | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP54 | c.2889+1G>A p.X963_splice | Splice Site (SNP) | VAF 34/98 reads (35%) | called by muse, varscan2
- CHAF1B | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CIBAR1 | c.599_600del p.E200Gfs*13 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- CISH | c.135G>T p.E45D (on ENST00000348721 / NM_145071.4; = p.E62D on NM_013324.6) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CLDN11 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 170/527 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CMTR2 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CNDP2 | c.61-1_61del p.X21_splice | Splice Site (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- CNTN3 | c.2075A>G p.K692R | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL25A1 | c.1719del p.G574Efs*36 | Frame Shift Del (DEL) | VAF 79/326 reads (24%) | called by mutect2, pindel, varscan2
- CORO1B | c.173del p.G58Vfs*8 | Frame Shift Del (DEL) | VAF 114/362 reads (31%) | called by mutect2, pindel, varscan2
- COX10 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 46/1350 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CPAMD8 | c.3805G>A p.A1269T (on ENST00000651564; = p.A1222T on NM_015692.5) | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPB1 | c.358A>G p.N120D | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CPXM2 | c.1573T>C p.Y525H | Missense Mutation (SNP) | VAF 115/548 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CST6 | c.82del p.A28Pfs*62 | Frame Shift Del (DEL) | VAF 123/379 reads (32%) | called by mutect2, pindel, varscan2
- CYP2J2 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 151/459 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYTL1 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DBX1 | c.856A>G p.S286G | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF17 | c.459-2A>T p.X153_splice | Splice Site (SNP) | VAF 107/351 reads (30%) | called by muse, mutect2, varscan2
- DCTN1 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 176/514 reads (34%) | called by muse, mutect2, varscan2
- DENND2A | c.1271del p.F424Sfs*18 | Frame Shift Del (DEL) | VAF 110/357 reads (31%) | called by mutect2, pindel, varscan2
- DENND4C | c.2876G>A p.S959N | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- DIXDC1 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 24/552 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2
- DNAAF4 | c.462del p.A155Pfs*41 | Frame Shift Del (DEL) | VAF 62/208 reads (30%) | called by mutect2, pindel, varscan2
- DNAH6 | c.2582A>G p.Q861R | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNASE1L2 | c.846T>C p.A282= | Splice Region (SNP) | VAF 84/288 reads (29%) | called by muse, mutect2, varscan2
- DNMT3L | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- E4F1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- EDC4 | c.3629G>T p.S1210I | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- EEF1A1 | c.1019T>C p.F340S | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1A1 | c.257_258del p.Y86Cfs*5 | Frame Shift Del (DEL) | VAF 44/207 reads (21%) | called by mutect2, pindel, varscan2
- ELAVL1 | c.770A>G p.E257G | Missense Mutation (SNP) | VAF 180/556 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELFN1 | c.2157del p.P721Hfs*40 | Frame Shift Del (DEL) | VAF 71/245 reads (29%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.2158-1G>T p.X720_splice | Splice Site (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2
- EPHX3 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- ERCC6L2 | c.593del p.K198Rfs*4 | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | called by pindel, varscan2
- ERGIC1 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 129/431 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ESS2 | c.248T>G p.I83S | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ETF1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EXOSC10 | c.1800+5_1800+6del | Splice Region (DEL) | VAF 72/275 reads (26%) | called by pindel, varscan2
- EZR | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 191/924 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, varscan2
- FAM160B2 | c.932C>A p.A311E | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); called by muse, mutect2
- FAM184B | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FANCI | c.3090C>G p.N1030K (on ENST00000310775 / NM_001376911.1; = p.N970K on NM_018193.3) | Missense Mutation (SNP) | VAF 221/658 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FARP1 | c.2621del p.P874Lfs*20 | Frame Shift Del (DEL) | VAF 101/320 reads (32%) | called by mutect2, pindel, varscan2
- FASN | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 72/440 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT3 | c.3260G>A p.G1087D | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- FEZ1 | c.498+6dup | Splice Region (INS) | VAF 34/137 reads (25%) | called by mutect2, pindel, varscan2
- FMOD | c.1003A>T p.T335S | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAB3 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 127/337 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GANAB | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GARS1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 118/445 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GBP5 | c.278T>C p.L93S | Missense Mutation (SNP) | VAF 177/536 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIN1 | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLMN | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 65/206 reads (32%) | called by muse, mutect2, varscan2
- GMEB2 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 96/257 reads (37%) | called by muse, mutect2, varscan2
- GNPTAB | c.2961T>A p.H987Q | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPC2 | c.583T>A p.L195M | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- GPR68 | c.581T>C p.F194S | Missense Mutation (SNP) | VAF 171/501 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRASP1 | c.3163G>T p.G1055C | Missense Mutation (SNP) | VAF 168/573 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRIK1 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN3B | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- HAO2 | c.215dup p.I73Yfs*15 | Frame Shift Ins (INS) | VAF 69/255 reads (27%) | called by mutect2, pindel, varscan2
- HDAC10 | c.1618T>G p.S540A | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HDAC7 | c.2857T>C p.*953Qext*? (on ENST00000427332; = p.*992Qext*36 on NM_015401.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 98/358 reads (27%) | called by muse, mutect2, varscan2
- HDLBP | c.1695del p.K565Nfs*89 | Frame Shift Del (DEL) | VAF 64/264 reads (24%) | called by mutect2, pindel, varscan2
- HIRIP3 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIVEP2 | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- HNRNPD | c.550del p.I184Ffs*15 | Frame Shift Del (DEL) | VAF 78/244 reads (32%) | called by mutect2, pindel, varscan2
- HOXB1 | c.428del p.P143Lfs*41 | Frame Shift Del (DEL) | VAF 22/217 reads (10%) | called by mutect2, varscan2
- HSPG2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 128/404 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IFRD1 | c.351A>C p.E117D | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- INAVA | c.481del p.E161Kfs*27 | Frame Shift Del (DEL) | VAF 66/416 reads (16%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1942_1945del p.L648Dfs*109 | Frame Shift Del (DEL) | VAF 86/330 reads (26%) | called by pindel, varscan2
- IRX2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGAM | c.2933T>C p.L978P (on ENST00000648685 / NM_001145808.2; = p.L977P on NM_000632.4) | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITGB8 | c.636T>C p.S212= | Splice Region (SNP) | VAF 74/297 reads (25%) | called by muse, mutect2, varscan2
- ITPR3 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- JRKL | c.1259T>C p.L420S | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNQ1 | c.2018A>G p.D673G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); called by muse, mutect2
- KDR | c.1255+2T>C p.X419_splice | Splice Site (SNP) | VAF 71/269 reads (26%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2740C>A p.L914I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA2013 | c.1135A>T p.S379C | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KIDINS220 | c.3095dup p.L1032Ffs*55 | Frame Shift Ins (INS) | VAF 85/302 reads (28%) | called by mutect2, pindel, varscan2
- KIF16B | c.3805A>G p.R1269G | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF7 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIFAP3 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIFBP | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 75/1131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- KLHL17 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 202/628 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL20 | c.1296-1G>T p.X432_splice | Splice Site (SNP) | VAF 67/314 reads (21%) | called by muse, mutect2, varscan2
- KLHL25 | c.1433G>C p.C478S | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KRT86 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 204/874 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, varscan2
- KRTAP5-1 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 150/420 reads (36%) | PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LAMA4 | c.5084A>G p.Y1695C (on ENST00000230538 / NM_001105206.3; = p.Y1688C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/734 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMC3 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 140/426 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LARP4B | c.1552dup p.T518Nfs*34 | Frame Shift Ins (INS) | VAF 47/212 reads (22%) | called by mutect2, pindel, varscan2
- LENG8 | c.2317G>A p.G773S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRFN5 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2
- LRP2 | c.13448C>T p.A4483V | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP3 | c.200del p.P67Rfs*17 | Frame Shift Del (DEL) | VAF 92/321 reads (29%) | called by mutect2, pindel, varscan2
- LRRC2 | c.178del p.Q60Rfs*10 | Frame Shift Del (DEL) | VAF 117/406 reads (29%) | called by mutect2, pindel, varscan2
- MACF1 | c.3667A>T p.K1223* | Nonsense Mutation (SNP) | VAF 127/422 reads (30%) | called by muse, mutect2, varscan2
- MACO1 | c.1993T>C p.*665Rext*53 | Nonstop Mutation (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- MAFA | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MAGI2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP3K12 | c.1305_1306del p.R435Sfs*9 | Frame Shift Del (DEL) | VAF 72/312 reads (23%) | called by pindel, varscan2
- MARCHF8 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MAST3 | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 171/487 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAST4 | c.7223C>T p.A2408V (on ENST00000403625 / NM_001164664.2; = p.A2219V on NM_015183.3) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAU2 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MBD6 | c.1068_1070del p.S358del | In Frame Del (DEL) | VAF 112/446 reads (25%) | called by pindel, varscan2
- MBTPS1 | c.2212T>C p.Y738H | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- MDN1 | c.14307G>T p.E4769D | Missense Mutation (SNP) | VAF 150/604 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MDN1 | c.12245A>G p.E4082G | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MDN1 | c.3634A>G p.R1212G | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED1 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 147/430 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MED14 | c.4180G>A p.G1394S | Missense Mutation (SNP) | VAF 131/475 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- MEFV | c.1883G>T p.R628M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MEP1A | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 74/320 reads (23%) | called by muse, mutect2, varscan2
- MISP | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 221/657 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MISP | c.760del p.V254Wfs*78 | Frame Shift Del (DEL) | VAF 59/247 reads (24%) | called by mutect2, pindel, varscan2
- MMP23B | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 136/693 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGAT3 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MON2 | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MPP4 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP6 | c.587del p.N196Ifs*8 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | called by mutect2, pindel, varscan2
- MTERF4 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MTX1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MUC12 | c.2956A>G p.T986A (on ENST00000379442; = p.T843A on NM_001164462.1) | Missense Mutation (SNP) | VAF 126/879 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- MYCBP2 | c.10853T>C p.L3618S (on ENST00000357337; = p.L3656S on NM_015057.5) | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYCBP2 | c.1124del p.K375Sfs*4 (on ENST00000357337; = p.K413Sfs*4 on NM_015057.5) | Frame Shift Del (DEL) | VAF 47/173 reads (27%) | called by mutect2, pindel, varscan2
- MYH11 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 177/680 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK3 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 186/606 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- NARF | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NCKAP5 | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NEIL2 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NELL2 | c.681C>A p.T227= | Splice Region (SNP) | VAF 111/317 reads (35%) | called by muse, mutect2, varscan2
- NEURL3 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NFASC | c.2243G>T p.W748L (on ENST00000339876 / NM_001378329.1; = p.W744L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFU1 | c.260A>T p.D87V (on ENST00000410022 / NM_001002755.4; = p.D63V on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- NOC2L | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NOTCH1 | c.5498A>G p.D1833G | Missense Mutation (SNP) | VAF 200/753 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NOTCH4 | c.1328del p.P443Qfs*63 | Frame Shift Del (DEL) | VAF 52/230 reads (23%) | called by mutect2, pindel
- NRK | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NRXN2 | c.4702C>T p.R1568* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- NSD2 | c.50del p.K17Sfs*3 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- NSRP1 | c.257del p.K86Rfs*23 | Frame Shift Del (DEL) | VAF 54/190 reads (28%) | called by mutect2, varscan2
- NSUN3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR8D4 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR8G2P | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OSBPL10 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PC | c.2434dup p.A812Gfs*22 | Frame Shift Ins (INS) | VAF 88/334 reads (26%) | called by mutect2, pindel, varscan2
- PCDHA7 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 178/572 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB10 | c.1347del p.A450Pfs*92 | Frame Shift Del (DEL) | VAF 260/918 reads (28%) | called by mutect2, pindel, varscan2
- PCM1 | c.4750C>T p.P1584S | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- PCYOX1L | c.991C>G p.P331A | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PDE1A | c.1573A>G p.T525A | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, varscan2
- PDE4DIP | c.902A>C p.Y301S | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDZRN3 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); called by muse, varscan2
- PEAK1 | c.3732G>T p.K1244N | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- PEX26 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PGF | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 103/364 reads (28%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 182/550 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PHF10 | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PHF21A | c.1553dup p.L519Sfs*53 (on ENST00000418153 / NM_001101802.3; = p.L473Sfs*53 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- PI4KA | c.6079G>A p.V2027M | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PKP1 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PLA2G15 | c.695del p.G232Afs*23 | Frame Shift Del (DEL) | VAF 52/166 reads (31%) | called by mutect2, pindel
- PLAT | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 85/299 reads (28%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLCB2 | c.3354+1G>T p.X1118_splice | Splice Site (SNP) | VAF 70/193 reads (36%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2097G>A p.M699I | Missense Mutation (SNP) | VAF 146/471 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNPLA6 | c.3631C>A p.Q1211K (on ENST00000414982 / NM_001166111.2; = p.Q1163K on NM_006702.5) | Missense Mutation (SNP) | VAF 176/580 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- POC5 | c.1142C>T p.T381I (on ENST00000428202 / NM_001099271.2; = p.T356I on NM_152408.2) | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- POLG | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 244/751 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPFIA1 | c.3361G>T p.G1121W | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PPM1G | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R5B | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPRC1 | c.2670dup p.S891Qfs*11 | Frame Shift Ins (INS) | VAF 57/301 reads (19%) | called by mutect2, pindel, varscan2
- PRKCG | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PRKDC | c.7174G>T p.V2392L | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PSMB11 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PSMD2 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTCD3 | c.1535T>A p.I512N | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PTCHD3 | c.2161A>G p.N721D | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PTPN13 | c.1384A>G p.S462G | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PWWP2A | c.119del p.L40Pfs*100 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- R3HDM4 | c.483dup p.A162Rfs*76 | Frame Shift Ins (INS) | VAF 32/109 reads (29%) | called by mutect2, pindel
- RAB33A | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 141/434 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RALYL | c.127del p.S43Qfs*6 | Frame Shift Del (DEL) | VAF 94/364 reads (26%) | called by mutect2, pindel, varscan2
- RB1 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RBBP6 | c.4637A>C p.K1546T | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- RBM19 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBM4B | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- REN | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 259/1554 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGL4 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 191/533 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- RIF1 | c.4514del p.K1505Rfs*18 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | called by mutect2, varscan2
- RNF157 | c.1853A>G p.N618S | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); called by muse, mutect2
- ROS1 | c.472dup p.L158Pfs*6 | Frame Shift Ins (INS) | VAF 93/383 reads (24%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRAGA | c.63_69del p.S22Gfs*3 | Frame Shift Del (DEL) | VAF 85/248 reads (34%) | called by mutect2, pindel, varscan2
- RUSF1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SART1 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SCN5A | c.2525T>C p.L842P | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SCYL1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SEC24D | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- SEMA4F | c.2023C>A p.L675M | Missense Mutation (SNP) | VAF 113/414 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA4G | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SERINC1 | c.940C>G p.H314D | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD1B | c.938A>G p.H313R | Missense Mutation (SNP) | VAF 128/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETD2 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCD | c.586A>G p.T196A (on ENST00000435422 / NM_001128209.2; = p.T197A on NM_000337.5) | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- SGSM3 | c.1553G>A p.W518* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- SH2D3A | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SHANK1 | c.4552del p.V1518Sfs*107 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.3217T>G p.W1073G | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SIGLEC14 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 32/127 reads (25%) | called by mutect2, varscan2
- SIN3A | c.281dup p.H94Qfs*38 | Frame Shift Ins (INS) | VAF 107/386 reads (28%) | called by mutect2, pindel, varscan2
- SIN3B | c.3306G>A p.W1102* | Nonsense Mutation (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- SIPA1 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SKIV2L | c.2830T>C p.F944L | Missense Mutation (SNP) | VAF 106/466 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC1A1 | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 170/616 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- SLC1A2 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC26A8 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC39A3 | c.610del p.V204Wfs*33 | Frame Shift Del (DEL) | VAF 82/246 reads (33%) | called by mutect2, pindel, varscan2
- SLC44A1 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SLC44A4 | c.1832-2A>G p.X611_splice | Splice Site (SNP) | VAF 88/332 reads (27%) | called by muse, mutect2, varscan2
- SLC5A8 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 94/310 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SLC7A10 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC7A4 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMIM30 | c.-124+3A>G | Splice Region (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- SPEN | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPINK5 | c.1487G>A p.C496Y | Missense Mutation (SNP) | VAF 118/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPOPL | c.1082A>G p.Q361R | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRY3 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 197/610 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRCIN1 | c.45del p.M16Cfs*44 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- SRRM2 | c.7715C>A p.P2572H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SRSF3 | c.262A>G p.R88G | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STOX1 | c.2324T>C p.I775T | Missense Mutation (SNP) | VAF 115/519 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STX11 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 194/767 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SVEP1 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SYBU | c.188G>A p.G63E (on ENST00000276646 / NM_001099754.2; = p.G62E on NM_017786.6) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SYT4 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SZT2 | c.10217dup p.A3407Cfs*40 (on ENST00000634258 / NM_001365999.1; = p.A3350Cfs*40 on NM_015284.4) | Frame Shift Ins (INS) | VAF 51/206 reads (25%) | called by mutect2, pindel, varscan2
- TADA3 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TAF11 | c.622del p.I208Sfs*33 | Frame Shift Del (DEL) | VAF 60/277 reads (22%) | called by mutect2, pindel, varscan2
- TBL1X | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 127/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBX21 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCEA3 | c.113T>C p.M38T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TCF21 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 117/469 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TCHHL1 | c.2177A>C p.E726A | Missense Mutation (SNP) | VAF 101/434 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TECPR1 | c.1985T>C p.I662T | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TENT2 | c.248del p.N83Tfs*20 | Frame Shift Del (DEL) | VAF 48/172 reads (28%) | called by mutect2, pindel, varscan2
- TH | c.1003G>A p.A335T (on ENST00000381178 / NM_199292.3; = p.A304T on NM_000360.4) | Missense Mutation (SNP) | VAF 185/603 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THAP9 | c.454del p.R152Dfs*5 | Frame Shift Del (DEL) | VAF 68/223 reads (30%) | called by mutect2, pindel, varscan2
- TJP1 | c.1141_1143del p.S381del | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel
- TLN1 | c.4709A>G p.D1570G | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TMEM102 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM63B | c.589A>G p.N197D | Missense Mutation (SNP) | VAF 108/531 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TMPRSS6 | c.2378T>C p.V793A | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TMTC3 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNRC6B | c.4307A>G p.Q1436R (on ENST00000454349 / NM_001162501.2; = p.Q1326R on NM_015088.3) | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TOR1AIP2 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 116/700 reads (17%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TRIM35 | c.1092del p.L365Cfs*47 | Frame Shift Del (DEL) | VAF 106/338 reads (31%) | called by mutect2, pindel, varscan2
- TRIM37 | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIP11 | c.2104C>A p.Q702K | Missense Mutation (SNP) | VAF 159/443 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPC3 | c.844A>G p.S282G (on ENST00000379645 / NM_001366479.2; = p.S209G on NM_003305.2) | Missense Mutation (SNP) | VAF 154/546 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TRPS1 | c.2841_2843del p.R948del (on ENST00000220888 / NM_001330599.2; = p.R961del on NM_014112.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- TTC39B | c.996G>A p.R332= | Splice Region (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- TTK | c.2441G>A p.G814D | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TTN | c.50186C>T p.T16729I (on ENST00000591111; = p.T9305I on NM_003319.4) | Missense Mutation (SNP) | VAF 75/239 reads (31%) | PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TTN | c.47035C>T p.Q15679* (on ENST00000591111; = p.Q8255* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2
- U2SURP | c.507T>A p.N169K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR4 | c.12235G>T p.G4079W | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- UBR4 | c.7147C>T p.R2383C | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- UBR5 | c.3060del p.I1021* | Frame Shift Del (DEL) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- UNC119B | c.507C>G p.N169K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.073); called by muse, varscan2
- UNC5B | c.2219A>G p.E740G | Missense Mutation (SNP) | VAF 133/473 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP18 | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USP49 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- USP9X | c.911dup p.N304Kfs*2 | Frame Shift Ins (INS) | VAF 52/183 reads (28%) | called by mutect2, pindel, varscan2
- USPL1 | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- WDR87 | c.4127del p.L1376* | Frame Shift Del (DEL) | VAF 90/268 reads (34%) | called by mutect2, pindel, varscan2
- WDR87 | c.3949A>T p.I1317F | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- WIZ | c.1066dup p.E356Gfs*8 | Frame Shift Ins (INS) | VAF 34/117 reads (29%) | called by mutect2, pindel, varscan2
- WNT16 | c.524G>A p.G175D (on ENST00000222462 / NM_057168.2; = p.G165D on NM_016087.2) | Missense Mutation (SNP) | VAF 166/574 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YOD1 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 100/759 reads (13%) | called by muse, mutect2, varscan2
- ZBTB48 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZCCHC3 | c.620del p.P207Rfs*8 | Frame Shift Del (DEL) | VAF 52/198 reads (26%) | called by mutect2, pindel, varscan2
- ZDHHC1 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ZDHHC23 | c.261del p.V88* | Frame Shift Del (DEL) | VAF 121/378 reads (32%) | called by mutect2, pindel, varscan2
- ZFAT | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ZFHX2 | c.7508T>C p.L2503P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZFHX3 | c.7417del p.Q2473Sfs*55 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4945_4949del p.S1649Hfs*11 | Frame Shift Del (DEL) | VAF 62/209 reads (30%) | called by mutect2, pindel, varscan2
- ZFP90 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF140 | c.275dup p.N92Kfs*5 | Frame Shift Ins (INS) | VAF 25/95 reads (26%) | called by pindel, varscan2
- ZNF148 | c.1183del p.I395Lfs*7 | Frame Shift Del (DEL) | VAF 120/453 reads (26%) | called by mutect2, pindel, varscan2
- ZNF23 | c.366del p.F122Lfs*35 | Frame Shift Del (DEL) | VAF 58/219 reads (26%) | called by mutect2, pindel, varscan2
- ZNF423 | c.3400A>G p.S1134G (on ENST00000563137 / NM_001379286.1; = p.S1126G on NM_015069.4) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF544 | c.1034_1036del p.N345del | In Frame Del (DEL) | VAF 47/213 reads (22%) | called by mutect2, pindel, varscan2
- ZNF587 | c.1483A>G p.S495G | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF653 | c.605G>C p.G202A | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF865 | c.2333T>C p.V778A | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.77); called by muse, mutect2, varscan2
- ZZEF1 | c.7160del p.K2387Sfs*40 | Frame Shift Del (DEL) | VAF 86/274 reads (31%) | called by mutect2, pindel, varscan2
- ZZZ3 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 103/267 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AARS1 | c.1743T>C p.G581= | Silent (SNP) | VAF 127/426 reads (30%) | called by muse, mutect2, varscan2
- ABL2 | c.915C>T p.G305= (on ENST00000502732 / NM_007314.4; = p.G290= on NM_005158.5) | Silent (SNP) | VAF 71/350 reads (20%) | catalogued as rs752208127, COSV100772920; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1851C>T p.C617= | Silent (SNP) | VAF 150/472 reads (32%) | catalogued as rs1314951341; called by muse, mutect2, varscan2
- ADRA1D | c.834C>T p.Y278= | Silent (SNP) | VAF 94/268 reads (35%) | catalogued as rs547077475; called by muse, mutect2, varscan2
- AGBL3 | c.154C>A p.R52= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV51949632; called by muse, mutect2, varscan2
- ANKRD17 | c.303C>A p.G101= | Silent (SNP) | VAF 130/352 reads (37%) | catalogued as rs755444217; called by muse, mutect2, varscan2
- AR | c.1128C>T p.P376= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as COSV65960006; called by muse, mutect2, varscan2
- ARAP2 | c.4987A>C p.R1663= | Silent (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.3126G>A p.A1042= (on ENST00000276826 / NM_001308208.2; = p.A1073= on NM_025251.2) | Silent (SNP) | VAF 133/445 reads (30%) | catalogued as rs1293421807, COSV52772601; called by muse, mutect2, varscan2
- ATG16L1 | c.1462T>C p.L488= (on ENST00000392017 / NM_030803.7; = p.L469= on NM_017974.4) | Silent (SNP) | VAF 80/225 reads (36%) | called by muse, mutect2, varscan2
- AUH | c.672G>A p.L224= | Silent (SNP) | VAF 111/338 reads (33%) | called by muse, mutect2, varscan2
- BHLHE22 | c.519G>T p.A173= | Silent (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2, varscan2
- BMPR2 | c.261C>T p.H87= | Silent (SNP) | VAF 89/354 reads (25%) | catalogued as rs1234205940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BYSL | c.831G>A p.K277= | Silent (SNP) | VAF 176/330 reads (53%) | catalogued as rs767843326; called by muse, mutect2, varscan2
- C1QTNF9B | c.615T>C p.T205= | Silent (SNP) | VAF 19/374 reads (5%) | catalogued as rs1248320002; called by muse, mutect2
- C1orf198 | c.756G>A p.Q252= | Silent (SNP) | VAF 66/256 reads (26%) | called by muse, mutect2, varscan2
- CAND1 | c.126T>C p.D42= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- CASKIN1 | c.3456C>A p.P1152= | Silent (SNP) | VAF 227/629 reads (36%) | called by muse, mutect2, varscan2
- CCDC185 | c.1023G>A p.P341= | Silent (SNP) | VAF 76/373 reads (20%) | catalogued as rs567585826; called by muse, mutect2, varscan2
- CCDC93 | c.183C>T p.I61= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as COSV60123719; called by muse, mutect2, varscan2
- CD5L | c.426C>T p.D142= | Silent (SNP) | VAF 90/405 reads (22%) | catalogued as rs748603519, COSV63821204; called by muse, mutect2, varscan2
- CELSR3 | c.108C>T p.G36= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs1292926570; called by muse, mutect2, varscan2
- CENPE | c.1428T>G p.L476= | Silent (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- CFAP43 | c.2985C>T p.S995= | Silent (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- CGN | c.3414G>A p.Q1138= | Silent (SNP) | VAF 72/422 reads (17%) | called by muse, mutect2, varscan2
- CILP2 | c.1803G>A p.G601= | Silent (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- CLPX | c.213T>C p.S71= | Silent (SNP) | VAF 11/93 reads (12%) | called by mutect2, varscan2
- CNOT1 | c.3783A>G p.A1261= | Silent (SNP) | VAF 93/304 reads (31%) | called by muse, mutect2, varscan2
- CORO2A | c.366G>T p.T122= | Silent (SNP) | VAF 72/269 reads (27%) | called by muse, mutect2, varscan2
- CPNE5 | c.1026C>A p.P342= | Silent (SNP) | VAF 85/509 reads (17%) | catalogued as COSV55198906; called by muse, mutect2, varscan2
- CPSF1 | c.4252C>T p.L1418= | Silent (SNP) | VAF 96/328 reads (29%) | catalogued as rs782631342; called by muse, mutect2, varscan2
- CRACD | c.1078A>C p.R360= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- CRB1 | c.2478G>A p.K826= | Silent (SNP) | VAF 140/760 reads (18%) | catalogued as COSV66330321; called by muse, mutect2, varscan2
- CRB2 | c.1128T>C p.T376= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as rs777045044; called by muse, mutect2, varscan2
- CT45A10 | c.348C>A p.P116= | Silent (SNP) | VAF 146/745 reads (20%) | catalogued as COSV65921350; called by muse, mutect2, varscan2
- CTPS1 | c.450C>T p.T150= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as rs779429212, COSV65451867; called by muse, mutect2, varscan2
- DDX50 | c.1140T>C p.D380= | Silent (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- DECR1 | c.546A>G p.Q182= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- DHX16 | c.1410T>C p.G470= | Silent (SNP) | VAF 170/758 reads (22%) | called by muse, mutect2, varscan2
- DNA2 | c.2358G>T p.G786= | Silent (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- DST | c.3006T>C p.P1002= (on ENST00000361203 / NM_001374722.1; = p.P676= on NM_001723.6) | Silent (SNP) | VAF 82/407 reads (20%) | called by muse, mutect2, varscan2
- DUSP16 | c.606C>T p.P202= | Silent (SNP) | VAF 116/367 reads (32%) | catalogued as rs189393014; called by muse, mutect2, varscan2
- EEF2 | c.585C>T p.G195= | Silent (SNP) | VAF 119/383 reads (31%) | catalogued as rs1246304491; called by muse, mutect2, varscan2
- EML5 | c.3837T>C p.C1279= | Silent (SNP) | VAF 140/402 reads (35%) | called by muse, mutect2, varscan2
- ENPP7 | c.27T>C p.T9= | Silent (SNP) | VAF 65/195 reads (33%) | called by muse, mutect2
- EP400 | c.9147G>A p.Q3049= | Silent (SNP) | VAF 93/257 reads (36%) | called by muse, mutect2, varscan2
- EPM2A | c.780C>T p.H260= | Silent (SNP) | VAF 108/449 reads (24%) | called by muse, mutect2, varscan2
- ERGIC1 | c.745C>T p.L249= | Silent (SNP) | VAF 120/338 reads (36%) | called by muse, mutect2, varscan2
- EXOC7 | c.528T>C p.G176= | Silent (SNP) | VAF 36/408 reads (9%) | called by muse, mutect2
- FAAP100 | c.357C>T p.D119= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs748868138; called by muse, mutect2, varscan2
- FAM167A | c.234G>A p.G78= | Silent (SNP) | VAF 108/300 reads (36%) | catalogued as rs778972735, COSV52702654, COSV52703303; called by muse, mutect2, varscan2
- FAM168A | c.516G>A p.Q172= (on ENST00000064778 / NM_001286050.2; = p.Q163= on NM_015159.3) | Silent (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2
- FAM189B | c.1479C>T p.S493= | Silent (SNP) | VAF 69/481 reads (14%) | catalogued as rs1047498623; called by muse, mutect2, varscan2
- FAT4 | c.2760T>C p.P920= | Silent (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- FLG2 | c.2952C>A p.S984= | Silent (SNP) | VAF 181/905 reads (20%) | called by muse, mutect2, varscan2
- FLRT2 | c.1599G>A p.T533= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV58144895; called by muse, mutect2, varscan2
- FMNL2 | c.294G>A p.R98= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as rs376652298; called by muse, mutect2, varscan2
- FNIP1 | c.951C>T p.S317= | Silent (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- FOXB2 | c.42G>A p.P14= | Silent (SNP) | VAF 176/518 reads (34%) | catalogued as COSV100942409, COSV65023597; called by muse, mutect2, varscan2
- FOXD4L4 | c.276A>G p.A92= | Silent (SNP) | VAF 66/1258 reads (5%) | called by muse, mutect2
- FOXE1 | c.720G>A p.P240= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as rs1428883579; called by muse, mutect2, varscan2
- FOXL1 | c.606G>A p.P202= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- FTSJ3 | c.450T>C p.R150= | Silent (SNP) | VAF 105/250 reads (42%) | catalogued as rs762905605; called by muse, mutect2, varscan2
- FZD3 | c.855C>A p.A285= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV53534965; called by muse, mutect2, varscan2
- GABRB3 | c.168C>T p.F56= | Silent (SNP) | VAF 140/392 reads (36%) | catalogued as COSV100157849; called by muse, mutect2, varscan2
- GCNT3 | c.1128T>C p.G376= | Silent (SNP) | VAF 99/327 reads (30%) | called by muse, mutect2, varscan2
- GDA | c.522T>C p.N174= | Silent (SNP) | VAF 71/263 reads (27%) | called by muse, mutect2, varscan2
- GDAP2 | c.1338A>G p.S446= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs1324663598; called by muse, mutect2, varscan2
- GGA3 | c.24C>T p.S8= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs1209318727; called by muse, mutect2, varscan2
- GGT2 | c.525G>A p.A175= | Silent (SNP) | VAF 100/602 reads (17%) | catalogued as rs757578986; called by muse, mutect2, varscan2
- GIGYF1 | c.1542C>T p.C514= | Silent (SNP) | VAF 178/569 reads (31%) | catalogued as rs770517974, COSV99309736; called by muse, mutect2, varscan2
- GLIS2 | c.681C>T p.R227= | Silent (SNP) | VAF 206/664 reads (31%) | called by muse, mutect2, varscan2
- GRM1 | c.2955G>A p.A985= | Silent (SNP) | VAF 64/256 reads (25%) | called by muse, mutect2, varscan2
- GSTP1 | c.213T>A p.R71= | Silent (SNP) | VAF 124/348 reads (36%) | called by muse, mutect2, varscan2
- HDAC1 | c.1404G>A p.E468= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as rs780146355; called by muse, mutect2
- HEATR1 | c.4159C>T p.L1387= | Silent (SNP) | VAF 147/759 reads (19%) | called by muse, mutect2, varscan2
- HEATR1 | c.2178G>A p.A726= | Silent (SNP) | VAF 68/269 reads (25%) | called by muse, mutect2, varscan2
- HMCN1 | c.12999C>T p.S4333= | Silent (SNP) | VAF 167/699 reads (24%) | catalogued as rs767099854, COSV99629732; called by muse, mutect2, varscan2
- HMCN2 | c.13740G>A p.L4580= | Silent (SNP) | VAF 162/505 reads (32%) | called by muse, varscan2
- HMGCR | c.1839A>G p.E613= | Silent (SNP) | VAF 11/302 reads (4%) | called by muse, mutect2
- HOXC11 | c.42G>A p.S14= | Silent (SNP) | VAF 53/167 reads (32%) | catalogued as COSV54532176; called by muse, mutect2, varscan2
- HSD17B8 | c.160C>T p.L54= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1429940955; called by muse, mutect2, varscan2
- HYI | c.72G>T p.V24= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs1361372567; called by muse, mutect2, varscan2
- IGKV3D-7 | c.66C>T p.T22= | Silent (SNP) | VAF 54/273 reads (20%) | catalogued as rs1407904981; called by muse, mutect2, varscan2
- IL17RD | c.1461C>T p.D487= | Silent (SNP) | VAF 96/277 reads (35%) | catalogued as rs1335167075, COSV56337999; called by muse, mutect2, varscan2
- IMPA2 | c.849G>A p.G283= | Silent (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- INPP5D | c.3423G>A p.P1141= (on ENST00000445964 / NM_001017915.3; = p.P1140= on NM_005541.5) | Silent (SNP) | VAF 136/398 reads (34%) | catalogued as rs1219801071, COSV64040879; called by muse, mutect2, varscan2
- INSIG1 | c.750T>C p.C250= | Silent (SNP) | VAF 103/381 reads (27%) | catalogued as COSV60920510; called by muse, mutect2, varscan2
- INTS1 | c.3546C>T p.D1182= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as rs368217287; called by muse, mutect2
- JUND | c.300C>T p.S100= | Silent (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2, varscan2
- KCNH6 | c.867G>A p.R289= | Silent (SNP) | VAF 156/372 reads (42%) | called by muse, mutect2, varscan2
- KDM4B | c.3135G>A p.P1045= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs771674735; called by muse, mutect2, varscan2
- KIF13B | c.5169C>T p.A1723= | Silent (SNP) | VAF 262/791 reads (33%) | catalogued as rs1393010827, COSV68094228; called by muse, mutect2, varscan2
- KIF2A | c.1350T>C p.H450= | Silent (SNP) | VAF 91/246 reads (37%) | catalogued as rs779537183, COSV66944442; called by muse, mutect2, varscan2
- KLF4 | c.168A>G p.P56= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as rs749135728; called by muse, mutect2
- KLHL33 | c.1276C>T p.L426= | Silent (SNP) | VAF 143/439 reads (33%) | called by muse, mutect2, varscan2
- KLHL9 | c.123T>C p.D41= | Silent (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- KMT2D | c.4146A>G p.V1382= | Silent (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- LAMB2 | c.5232C>T p.A1744= | Silent (SNP) | VAF 258/724 reads (36%) | catalogued as COSV59735386; called by muse, mutect2, varscan2
- LAMB3 | c.1734C>T p.C578= | Silent (SNP) | VAF 149/793 reads (19%) | catalogued as rs138710333; called by muse, mutect2, varscan2
- LGALS4 | c.168G>A p.P56= | Silent (SNP) | VAF 66/247 reads (27%) | catalogued as rs754742487; called by muse, mutect2, varscan2
- LIN54 | c.162T>C p.G54= | Silent (SNP) | VAF 95/333 reads (29%) | called by muse, mutect2, varscan2
- LRCOL1 | c.37C>T p.L13= | Silent (SNP) | VAF 125/372 reads (34%) | called by muse, mutect2, varscan2
245 further variants in this file (0 protein-altering or splice-affecting, 113 silent, 132 other) are not listed here.
